Gene-level copy-number profile of tumor specimen TCGA-D8-A1X5-01A from TCGA case TCGA-D8-A1X5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 81.4 years (29,734 days).
Specimen TCGA-D8-A1X5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.778e70fe-3515-4314-8035-c97e1970bf69.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1X5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e10f70fe-a058-4335-bf85-35d82837699b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,441; copy number 2: 21,608; copy number 3: 18,665; copy number 4: 8,704; copy number 5: 4,029; copy number 6: 2,143; copy number 7: 1,146; copy number 8: 1,458; copy number 9: 40; copy number 10: 210; copy number 11: 26; copy number 12: 197; copy number 13: 48; copy number 14: 11; copy number 15: 22; copy number 16: 5; copy number 17: 57; copy number 18: 2; copy number 22: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1X5-01A-11D-A14F-01): tumor purity 0.57, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,396 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,500,851–103,525,511, 199 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:104,998,406–248,919,946, 2,991 genes, copy number 5–10 (broad region; genes not listed).
- chr3:149,517,235–151,565,995, 54 genes, copy number 6: WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186.
- chr3:166,160,021–198,222,513, 628 genes, copy number 6 (broad region; genes not listed).
- chr4:17,614,641–18,021,876, 6 genes, copy number 9–16 (within-gene range 3–16): MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63.
- chr4:20,251,905–20,752,907, 4 genes, copy number 7: SLIT2, SLIT2-IT1, MIR218-1, PACRGL.
- chr4:20,766,808–20,767,372, 1 gene, copy number 7: AC097505.1.
- chr4:21,949,015–22,516,066, 3 genes, copy number 6–22 (within-gene range 5–24): AC096719.1, RNU6-420P, ADGRA3.
- chr4:24,517,441–25,863,760, 31 genes, copy number 6 (within-gene range 3–6): DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3.
- chr4:36,902,242–36,913,339, 1 gene, copy number 18 (within-gene range 3–18): AC093746.1.
- chr4:38,966,744–45,480,136, 115 genes, copy number 5–7 (broad region; genes not listed).
- chr5:18,886,622–21,196,860, 17 genes, copy number 5: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1.
- chr5:22,580,225–22,580,819, 1 gene, copy number 5: GCNT1P2.
- chr6:167,607–14,646,638, 273 genes, copy number 5 (broad region; genes not listed).
- chr8:49,496,763–145,066,685, 1,468 genes, copy number 6–11 (broad region; genes not listed).
- chr11:67,374,416–76,144,232, 325 genes, copy number 5–17 (within-gene range 2–17) (broad region; genes not listed).
- chr11:76,591,023–86,069,882, 137 genes, copy number 5–16 (within-gene range 4–16) (broad region; genes not listed).
- chr11:86,791,059–86,952,910, 1 gene, copy number 6 (within-gene range 4–6): PRSS23.
- chr11:86,857,059–87,330,052, 12 genes, copy number 6: OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1.
- chr14:21,918,188–22,507,723, 80 genes, copy number 6 (broad region; genes not listed).
- chr16:11,555–35,912,516, 1,419 genes, copy number 5–6 (broad region; genes not listed).
- chr17:26,989,189–31,769,048, 255 genes, copy number 5 (broad region; genes not listed).
- chr17:36,722,443–36,726,346, 1 gene, copy number 18: AC243830.1.
- chr17:37,609,739–38,800,126, 43 genes, copy number 9–15 (within-gene range 3–15): AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B.
- chr17:39,671,122–40,115,442, 23 genes, copy number 17 (within-gene range 3–17): PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1.
- chr17:40,958,417–41,668,031, 70 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:61,865,367–83,095,122, 705 genes, copy number 6 (broad region; genes not listed).
- chr20:34,688,688–37,317,260, 91 genes, copy number 5 (broad region; genes not listed).
- chr20:46,008,908–64,313,132, 442 genes, copy number 5–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
